TCGA case TCGA-A2-A0YI — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/72cd1b17-d349-4551-83f7-3062ce9db865

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct and lobular carcinoma: ICD-O-3 morphology code: 8522/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.9 years (22,961 days); Year of diagnosis: 2009; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1c; AJCC pathologic N: N0 (i+); AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 3; Micrometastasis present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 77 days; Days to treatment end: 116 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (3 entries)
- Days to follow up: 358 days; Disease response: Tumor Free.
- Days to follow up: 441 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 1,505 days (4.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ESR1 (IHC): Positive; Staining intensity value: 3+; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity value: 2+; Test value range: 60-69%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A0YI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 340 mg.
  Slide TCGA-A2-A0YI-01A-03-BSC: Section location: Bottom; Percent tumor cells: 59; Percent tumor nuclei: 85; Percent normal cells: 20; Percent necrosis: 1; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A2-A0YI-01A-03-TSC: Section location: Top; Percent tumor cells: 69; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 1; Percent stromal cells: 10; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A0YI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A0YI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Axillary staging method other: Sentinel Lymph node biopsy and one non-sentinel lymph node biopsy; Surgical procedure first: Lumpectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: Yes; Er IHC score: 3+; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined IHC count: 1; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Femara.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,505 days; disease-specific survival: no event (censored), 1,505 days; disease-free interval: no event (censored), 1,505 days; progression-free interval: no event (censored), 1,505 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A0YI-01A-31D-A10L-01): tumor purity 0.44, ploidy 2.02, whole-genome doublings 0.
